Somatic mutation profile of tumor specimen HCM-BROD-0010-C25-06A (aliquot HCM-BROD-0010-C25-06A-01D-A78W-36) from HCMI case HCM-BROD-0010-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G3; Age at diagnosis: 53.9 years (19,673 days).
Specimen HCM-BROD-0010-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d647610-1491-44dd-8b69-46faaf755b38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0010-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0010-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a38e249a-8974-411e-a6ca-3d0160992692

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, Intron 2, RNA 2, Nonsense Mutation 2, Frame Shift Del 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 724/933 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 209/302 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP21 | c.3623T>C p.I1208T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs367814916; called by muse, mutect2, varscan2
- FIGN | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV60769256; called by muse, mutect2, varscan2
- GPR176 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs373118560; called by muse, mutect2, varscan2
- GYS2 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 130/443 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs373682083; called by muse, mutect2, varscan2
- ITFG2 | c.405C>T p.I135= | Splice Region (SNP) | VAF 116/369 reads (31%) | catalogued as rs374998892; called by muse, mutect2, varscan2
- LIMK1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs370710652, COSV100283349; called by muse, mutect2, varscan2
- MNDA | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as COSV63740672; called by muse, mutect2, varscan2
- RBFOX1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776698363, COSV60952220; called by muse, mutect2, varscan2
- SGIP1 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV99390485; called by muse, mutect2, varscan2
- SNTG1 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs867068094, COSV52461875, COSV99385396; called by muse, mutect2, varscan2
- SPTA1 | c.6730C>A p.Q2244K | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934287; called by muse, mutect2, varscan2
- TBXA2R | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780269189; called by muse, mutect2
- UHRF1BP1L | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | catalogued as rs1376524072, COSV99691528; called by muse, mutect2, varscan2
- USP9X | c.5131A>G p.S1711G | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV100198245; called by muse, mutect2, varscan2
- ZNF749 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs373133672; called by muse, mutect2, varscan2
- ZNF787 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1372299933; called by muse, varscan2
- CD1C | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- FAM193A | c.1237C>A p.H413N | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- FCHSD1 | c.1927C>G p.P643A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFE2L3 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- NIPBL | c.7560T>G p.N2520K | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NUDT9 | c.1020_1021del p.S340Rfs*4 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- OTOG | c.773C>G p.A258G | Missense Mutation (SNP) | VAF 198/286 reads (69%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- TRERF1 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- VILL | c.878T>G p.I293S | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB22 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- COL6A5 | c.5559C>T p.N1853= (on ENST00000312481; = p.N1849= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/511 reads (12%) | catalogued as rs1434690072; called by muse, mutect2, varscan2
- CPNE9 | c.153G>T p.R51= | Silent (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- DNM1L | c.108C>T p.S36= | Silent (SNP) | VAF 65/224 reads (29%) | catalogued as rs182756299; ClinVar: likely benign; called by muse, mutect2, varscan2
- MKLN1 | c.405A>G p.P135= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as rs761391733; called by muse, mutect2, varscan2
- MORC4 | c.2412G>A p.Q804= | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, varscan2
- PLXDC2 | c.1353C>A p.T451= | Silent (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- TCERG1L | c.1200C>T p.S400= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as rs757435830; called by muse, mutect2, varscan2
- UNC80 | c.7716C>T p.D2572= | Silent (SNP) | VAF 149/408 reads (37%) | called by muse, mutect2, varscan2
- COL20A1 | c.3295-77G>T | Intron (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- EPS15 | c.1041-87A>C | Intron (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.268C>T | RNA (SNP) | VAF 60/368 reads (16%) | catalogued as rs765100841; called by muse, mutect2, varscan2
- STAG3L4 | n.503C>T | RNA (SNP) | VAF 34/210 reads (16%) | called by muse, mutect2, varscan2
